Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAVY, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAVY-01A (Primary Tumor).

DIAGNOSIS:

Liver, right, hemihepatectomy:

Hepatocellular carcinoma

- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 20.5x16x11cm
- 3) Gross type: multinodular confluent
- 4) Satellite nodule: present
- 5) Histologic type: trabecular and pseudoglandular
- 6) Cell type: classic and clear cell group
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 3
The major differentiation: 2
- 8) Fatty change: absent
- 9) Hemorrhage/peliosis: present (10%)
- 10) Tumor necrosis: present (10%)
- 11) Vascular invasion(microscopic): present
- 12) Capsule formation: partial
- 13) Infiltration of capsule: present
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: present
- 19) Surgical margin: clear (safety margin: 0.1cm)
- 20) Intrahepatic metastasis: present
- 21) Multicentric occurrence: absent
- 22) Pathologic stage: AJCC (pT3), (pT4)
- 23) Related biopsy: none
- 24) Additional pathologic findings
- a) Chronic hepatitis: absent
- b) Cirrhosis: absent
- c) Dysplasia: absent

ICD-O-3

Carcinoma, hepatocellular
NOS 8170/3

Date Liver CB2.0

JA 4/23/14

Source: NCI Genomic Data Commons file 3f92c985-56ca-42a5-89d7-a65ad852456a (TCGA-DD-AAVY.ADDCC231-66AE-4136-AAEC-DCA3DA1C4159.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).